CCDI case PBBUTL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/715b31d4-5ab7-4b07-b679-921871b25b5f

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 3.7 years (1,341 days).

Biospecimens (3 samples)
- Sample 0DHPJ9: Tissue type: Normal; Specimen type: Peripheral Whole Blood. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample 0DHPJC: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DHPK2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
